Somatic mutation profile of tumor specimen MMRF_2550_1_BM_CD138pos (aliquot MMRF_2550_1_BM_CD138pos_T1_KHS5U_K15135) from MMRF case MMRF_2550, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.9 years (22,969 days).
Specimen MMRF_2550_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 492d873a-a1cf-4955-8a83-26e832199d30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2550_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2550_1_PB_Whole_C3_KHS5U_K15134; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d3ab0f2-4f98-42d2-84e2-f289c00a97ec

The open-access MAF lists 100 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 26, Silent 13, Intron 13, 5'UTR 5, Nonsense Mutation 3, 3'Flank 2, 5'Flank 2, Frame Shift Del 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.4426G>C p.E1476Q | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99287084; called by muse, mutect2, varscan2
- ADGRL2 | c.4088T>C p.L1363P (on ENST00000370717 / NM_001366005.1; = p.L1307P on NM_012302.4) | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs758837991; called by muse, mutect2
- BCLAF1 | c.563A>T p.K188I | Missense Mutation (SNP) | VAF 113/393 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV62140867; called by muse, mutect2, varscan2
- BHLHE40 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 122/253 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV56576084; called by muse, mutect2, varscan2
- CDKN1B | c.263A>G p.Y88C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57430217; called by muse, mutect2, varscan2
- CEP350 | c.3833C>G p.S1278C | Missense Mutation (SNP) | VAF 194/311 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV62603370, COSV62610858; called by muse, mutect2, varscan2
- DUSP2 | c.428G>A p.C143Y | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752250965; called by muse, mutect2, varscan2
- F2 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs756544259; called by muse, mutect2, varscan2
- GNAT1 | c.391G>A p.G131S | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs752708194; called by muse, mutect2, varscan2
- H2BW2 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 399/420 reads (95%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.028); catalogued as rs782738353; called by muse, mutect2, varscan2
- IGLV3-1 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 120/233 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs142180628; called by muse, varscan2
- IRX4 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51475485; called by muse, varscan2
- LANCL1 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 18/267 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52065663; called by muse, mutect2
- LMNTD1 | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104391737; called by muse, mutect2, varscan2
- MICAL2 | c.4840C>T p.P1614S | Missense Mutation (SNP) | VAF 24/301 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV99812035; called by muse, mutect2
- PEAR1 | c.2845C>T p.P949S | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV52776269; called by muse, mutect2
- RB1 | c.1651del p.E551Nfs*60 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as COSV57327592; called by mutect2, pindel, varscan2
- SIK3 | c.1994G>A p.R665H (on ENST00000445177 / NM_001366686.2; = p.R623H on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764373928; called by muse, mutect2, varscan2
- TAS2R43 | c.912G>C p.E304D | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs1565644799; called by muse, mutect2
- B3GALT5 | c.686T>A p.V229E | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAJC5 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.285); called by muse, mutect2
- FAM160B1 | c.2045A>C p.N682T | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GCG | c.219T>G p.D73E | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.061); called by muse, mutect2
- H4C2 | c.297C>G p.Y99* | Nonsense Mutation (SNP) | VAF 118/234 reads (50%) | called by muse, mutect2
- IGHV2-70D | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV2-70D | c.185del p.P62Qfs*23 | Frame Shift Del (DEL) | VAF 39/110 reads (35%) | called by pindel, varscan2
- IL1RAPL2 | c.1158C>G p.Y386* | Nonsense Mutation (SNP) | VAF 93/99 reads (94%) | called by muse, mutect2, varscan2
- PEAK1 | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 132/423 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- RAPGEF6 | c.3166G>T p.A1056S | Missense Mutation (SNP) | VAF 22/373 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.068); called by muse, mutect2
- RPRD1B | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SBK3 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 116/361 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SEMA3D | c.1542G>C p.K514N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- STRA6 | c.980C>A p.A327E | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- STT3B | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2, varscan2
- STX16 | c.59A>C p.N20T | Missense Mutation (SNP) | VAF 88/211 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TM9SF4 | c.293A>G p.K98R | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- TMEM242 | c.82G>C p.V28L | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2
- TNFAIP8 | c.31+2T>G p.X11_splice | Splice Site (SNP) | VAF 45/188 reads (24%) | called by muse, varscan2
- ABCA7 | c.390C>T p.A130= | Silent (SNP) | VAF 43/172 reads (25%) | called by muse, mutect2, varscan2
- ABCG1 | c.636G>A p.T212= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as rs779168440; called by muse, mutect2, varscan2
- AEBP2 | c.1215G>A p.A405= | Silent (SNP) | VAF 86/159 reads (54%) | catalogued as rs200116890, COSV56861535; called by muse, mutect2, varscan2
- CDC27 | c.1323A>G p.K441= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as rs199754068; called by muse, mutect2, varscan2
- CLTA | c.711C>T p.V237= (on ENST00000242285 / NM_007096.4; = p.V207= on NM_001833.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 104/221 reads (47%) | called by muse, mutect2, varscan2
- CYP4A22 | c.495T>C p.S165= | Silent (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2
- EHMT2 | c.1828C>T p.L610= | Silent (SNP) | VAF 50/137 reads (36%) | called by muse, mutect2, varscan2
- FBLN1 | c.1398G>A p.R466= | Silent (SNP) | VAF 52/130 reads (40%) | called by muse, mutect2, varscan2
- JPH2 | c.849C>A p.I283= | Silent (SNP) | VAF 10/131 reads (8%) | catalogued as rs1286994114, COSV65904878; called by muse, mutect2
- NKD2 | c.234C>T p.R78= | Silent (SNP) | VAF 106/154 reads (69%) | catalogued as rs377509658; called by muse, mutect2, varscan2
- SALL3 | c.1830C>T p.D610= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as rs375965369; called by muse, mutect2, varscan2
- SAMD15 | c.1851C>T p.I617= | Silent (SNP) | VAF 8/161 reads (5%) | catalogued as rs1185018667; called by muse, mutect2
- TRPC3 | c.294G>A p.P98= (on ENST00000379645 / NM_001366479.2; = p.P25= on NM_003305.2) | Silent (SNP) | VAF 83/192 reads (43%) | catalogued as rs751687075, COSV99312009, COSV99312648; called by muse, mutect2, varscan2
- ACTR3C | c.*39-494G>A | Intron (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- ADGRL3 | chr4:62072174 T>G | 3'Flank (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.1472+95G>A | Intron (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- BRD9 | c.967-87dup | Intron (INS) | VAF 29/129 reads (22%) | called by mutect2, pindel, varscan2
- CAMK2D | chr4:113761196 A>C | 5'Flank (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- CAMK2D | chr4:113761197 G>A | 5'Flank (SNP) | VAF 20/57 reads (35%) | catalogued as COSV99594548; called by muse, mutect2, varscan2
- CC2D1B | c.*73G>A | 3'UTR (SNP) | VAF 13/198 reads (7%) | called by muse, mutect2
- CCDC73 | c.429+741T>G | Intron (SNP) | VAF 42/91 reads (46%) | called by muse, mutect2, varscan2
- CDH19 | c.*2014A>G | 3'UTR (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2, varscan2
- CEMIP | c.*1536C>T | 3'UTR (SNP) | VAF 112/305 reads (37%) | called by muse, mutect2, varscan2
- CMPK1 | c.-19T>C | 5'UTR (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2
- CPXM2 | c.*273A>G | 3'UTR (SNP) | VAF 11/196 reads (6%) | catalogued as COSV53867328; called by muse, mutect2
- DISP2 | c.*205G>A | 3'UTR (SNP) | VAF 53/155 reads (34%) | called by muse, mutect2, varscan2
- DLGAP2 | c.*686G>A | 3'UTR (SNP) | VAF 11/212 reads (5%) | catalogued as rs1485086994; called by muse, mutect2
- DNAJA3 | c.784-61C>A | Intron (SNP) | VAF 90/186 reads (48%) | called by muse, varscan2
- DYRK1A | c.*223A>T | 3'UTR (SNP) | VAF 56/128 reads (44%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.-46G>A | 5'UTR (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- FGA | c.*525C>T | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- FLT4 | c.*437T>C | 3'UTR (SNP) | VAF 28/175 reads (16%) | called by muse, mutect2, varscan2
- G3BP2 | c.*1737G>C | 3'UTR (SNP) | VAF 36/88 reads (41%) | called by muse, mutect2, varscan2
- GLDN | c.*2760A>C | 3'UTR (SNP) | VAF 55/195 reads (28%) | called by muse, mutect2, varscan2
- GRIA2 | c.1266+93G>T | Intron (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2
- HMGB4 | c.-1112G>C | 5'UTR (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- IGLL5 | c.-224G>A | 5'UTR (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- KIAA1841 | c.*1108C>A | 3'UTR (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2, varscan2
- LMF1 | c.503+6877C>T | Intron (SNP) | VAF 68/115 reads (59%) | catalogued as rs186456368; called by muse, mutect2, varscan2
- NLRP12 | c.-17G>A | 5'UTR (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- NXPH1 | c.*980T>G | 3'UTR (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- OR5AK4P | n.267A>C | RNA (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2
- PARP14 | c.*1275T>C | 3'UTR (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- PBXIP1 | c.*602A>G | 3'UTR (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2, varscan2
- PHF20L1 | c.*1129G>A | 3'UTR (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- PLCE1 | c.*24+261A>G | Intron (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2
- PLCXD3 | c.*143T>A | 3'UTR (SNP) | VAF 35/140 reads (25%) | called by muse, mutect2, varscan2
- RAB3GAP2 | c.*2496G>C | 3'UTR (SNP) | VAF 72/108 reads (67%) | called by muse, mutect2, varscan2
- REG4 | c.165+1269G>T | Intron (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- RPS13 | c.321+117G>A | Intron (SNP) | VAF 78/182 reads (43%) | called by muse, mutect2, varscan2
- SEPTIN10 | c.1349+526C>T | Intron (SNP) | VAF 107/224 reads (48%) | catalogued as rs374928726, COSV100454344; called by muse, mutect2, varscan2
- SLC12A1 | c.629-1312A>T | Intron (SNP) | VAF 43/134 reads (32%) | called by muse, mutect2, varscan2
- SLC12A1 | c.725-631G>T | Intron (SNP) | VAF 31/118 reads (26%) | called by muse, varscan2
- SLC6A5 | c.*437G>C | 3'UTR (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- SLC6A5 | c.*554A>T | 3'UTR (SNP) | VAF 7/59 reads (12%) | catalogued as rs1389612300; called by muse, mutect2, varscan2
- SNAPIN | c.*193A>C | 3'UTR (SNP) | VAF 23/144 reads (16%) | called by muse, mutect2, varscan2
- SRBD1 | c.*5C>A | 3'UTR (SNP) | VAF 34/380 reads (9%) | called by muse, mutect2
- TLL2 | c.*1541C>G | 3'UTR (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- TMEM14B | c.*165A>C | 3'UTR (SNP) | VAF 56/127 reads (44%) | called by muse, mutect2, varscan2
- TRPS1 | chr8:115411885 A>C | 3'Flank (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- ZNF234 | c.*1403dup | 3'UTR (INS) | VAF 24/58 reads (41%) | called by mutect2, varscan2
- ZNF654 | c.*2145A>G | 3'UTR (SNP) | VAF 78/158 reads (49%) | called by muse, mutect2, varscan2
